MMRF case MMRF_1680 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e1c03e0f-273e-4119-8fda-5631a361c16f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.5 years (20,275 days); ISS stage: III; Days to last known disease status: 1,159 days (3.2 years); Days to last follow up: 1,159 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 132 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 27 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 28 days; Days to treatment end: 132 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 145 days; Days to treatment end: 145 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 146 days; Days to treatment end: 146 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): M Protein 7.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 88.5 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 8.6 µg/mL; Hemoglobin 5.7 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 22 g/L; Total Protein 12.1 g/dL; Glucose 8.53 mmol/L.
- Day 61 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 438 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 31 g/L; Total Protein 6.1 g/dL; Glucose 5.83 mmol/L.
- Day 182 (ECOG 0): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Hemoglobin 7.25 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 7.1 mmol/L.
- Day 272 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.71 mmol/L.
- Day 342 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Hemoglobin 8.18 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 6.38 mmol/L.
- Day 424 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Hemoglobin 8.18 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.33 mmol/L.
- Day 697: Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Glucose 6.22 mmol/L.
- Day 781 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 6.55 mmol/L.
- Day 865 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.39 mmol/L.
- Day 963 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 6.16 mmol/L.
- Day 1,061 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.
- Day 1,159 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Hemoglobin 7.38 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -9: Weight: 122 kg; Height: 184 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1680_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1680_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
